TCGA case TCGA-13-0764 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/034825d0-e8b7-4ac0-be31-25f6038cb04a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Dead; Days to death: 1,881 days (5.1 years); Population group: Ashkenazi Jew.

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 62.9 years (22,965 days); Year of diagnosis: 2006; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 160 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 160 days; Number of cycles: 6; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 160 days; Treatment dose: 15 mg/kg.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 63.6 years (23,237 days); Days to diagnosis: 272 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 63.6 years (23,237 days); Days to diagnosis: 272 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 272 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 272 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 944 days (2.6 years); Disease response: With Tumor.
- Days to follow up: 1,881 days (5.1 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-0764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.7; Intermediate dimension: 1.3; Shortest dimension: 0.4.
  Slide TCGA-13-0764-01A-03-BS3: Section location: Bottom; Percent tumor cells: 97; Percent tumor nuclei: 98; Percent normal cells: 2; Percent necrosis: 1.
  Slide TCGA-13-0764-01A-02-BS2: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 20; Percent necrosis: 1.
- Sample TCGA-13-0764-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Jewish religion heritage indicator: Ashkenazi.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Follow-up form 1: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.
- Follow-up form 2: Treatment outcome at TCGA followup: Progressive Disease; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,881 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,881 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 272 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-0764-01A-03D-0356-01): tumor purity 0.77, ploidy 3.93, whole-genome doublings 2.
